TCGA case TCGA-AJ-A3OJ — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: International Genomics Conosrtium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/76f98002-e8df-4dfa-926e-8bb2d5114966

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 54.3 years (19,826 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage II; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 467 days (1.3 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 95.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 81 days; Days to treatment end: 230 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 233 days; Days to treatment end: 263 days; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 274 days; Days to treatment end: 286 days; Treatment dose: 1,500 cGy; Treatment outcome: Complete Response; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Minimally Invasive; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (3 entries)
- Days to follow up: 59 days; Disease response: Tumor Free.
- Days to follow up: 467 days (1.3 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 104 kg; Height: 157 cm; BMI: 42.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AJ-A3OJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 260 mg.
  Slide TCGA-AJ-A3OJ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample TCGA-AJ-A3OJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AJ-A3OJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Indeterminate (neither Pre or Postmenopausal); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: Minimally Invasive.
- Follow-up form: Lost to follow-up: No; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 467 days; disease-specific survival: no event (censored), 467 days; disease-free interval: no event (censored), 467 days; progression-free interval: no event (censored), 467 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AJ-A3OJ-01A-11D-A227-01): tumor purity 0.63, ploidy 2, whole-genome doublings 0.
